Somatic mutation profile of tumor specimen 0DHBD2 from CCDI case PBBTSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,918 days).
Specimen 0DHBD2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10c33b6-c353-4dd5-8195-125efc5181ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHBCT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4a53ca8-ee14-49c3-b536-d7ad9a27e9b9

The open-access MAF lists 9,727 somatic variants for this specimen: 5,988 protein-altering or splice-affecting, 2,113 silent, 1,626 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,403, Silent 2,113, Intron 944, 3'UTR 395, Nonsense Mutation 329, 5'UTR 176, Splice Region 125, Splice Site 124, 5'Flank 39, RNA 36, 3'Flank 34, Translation Start Site 5.

Variants (750 of 9,727; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL5 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 132/377 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253768, CM1514237, COSV59938399; ClinVar: pathogenic; called by muse, varscan2
- ATM | c.5697C>A p.C1899* | Nonsense Mutation (SNP) | VAF 287/787 reads (36%) | catalogued as rs753839301, COSV53757233; ClinVar: pathogenic; called by muse, varscan2
- BTD | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs398123139, CM146367, COSV57730626; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CHD8 | c.5326C>T p.R1776* (on ENST00000646647 / NM_001170629.2; = p.R1497* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 145/378 reads (38%) | catalogued as rs1085307794; ClinVar: likely pathogenic; called by muse, varscan2
- CLN6 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs769701646, CM1512132; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- CPLANE1 | c.*1682C>T | 3'UTR (SNP) | VAF 142/668 reads (21%) | catalogued as rs863225163, COSV57054074; ClinVar: pathogenic; called by muse, varscan2
- CREBBP | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 135/370 reads (36%) | catalogued as rs1057520652, CM085342, COSV52135380; ClinVar: pathogenic; called by muse, varscan2
- CREBBP | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 23/202 reads (11%) | catalogued as rs1555484797, COSV52120614; ClinVar: pathogenic; called by muse, varscan2
- CYP26B1 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875231, CM119271, COSV50010732; ClinVar: likely pathogenic; called by muse, varscan2
- ERCC8 | c.400-1G>A p.X134_splice | Splice Site (SNP) | VAF 104/314 reads (33%) | catalogued as rs1057520280; ClinVar: likely pathogenic; called by muse, varscan2
- EXOSC9 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 164/455 reads (36%) | catalogued as rs372318863; ClinVar: pathogenic; called by muse, varscan2
- F8 | c.6682C>T p.R2228* | Nonsense Mutation (SNP) | VAF 170/216 reads (79%) | catalogued as rs137852355, CM002006, CM850003; ClinVar: pathogenic; called by muse, varscan2
- FANCA | c.2151+1G>A p.X717_splice | Splice Site (SNP) | VAF 102/219 reads (47%) | catalogued as rs1555548428; ClinVar: pathogenic; called by muse, varscan2
- FLI1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064797086; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FUS | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs121909671, CM091091, CM104703, COSV99568433; ClinVar: pathogenic; called by muse, varscan2
- GALT | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 144/363 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033802, CM990673, COSV100535360; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- IARS1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 188/534 reads (35%) | catalogued as rs886037875, COSV65115700; ClinVar: pathogenic; called by muse, varscan2
- IQCB1 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 158/428 reads (37%) | catalogued as rs1280238814, CM117872; ClinVar: pathogenic; called by muse, varscan2
- KIT | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 54/456 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560418178, CM950714, BM0795183, COSV55404737; ClinVar: likely pathogenic; called by muse, varscan2
- LAMA2 | c.3085C>T p.R1029* | Nonsense Mutation (SNP) | VAF 166/491 reads (34%) | catalogued as rs145420388, CM020725, COSV101370819; ClinVar: pathogenic; called by muse, varscan2
- MARVELD2 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 130/331 reads (39%) | catalogued as rs118203957, CM065299; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- MCOLN1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908374, CM043521; ClinVar: pathogenic; called by muse, varscan2
- MFRP | chr11:119343953 C>T | 5'Flank (SNP) | VAF 30/214 reads (14%) | catalogued as rs1166512859, COSV64129132; ClinVar: pathogenic; called by muse, varscan2
- MYL3 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs104893749, CM961008, COSV52768329; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 166/444 reads (37%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, varscan2
- NF1 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 169/459 reads (37%) | catalogued as rs886041347, CM971040, COSV62196183; ClinVar: pathogenic; called by muse, varscan2
- NPR2 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 84/686 reads (12%) | catalogued as rs121912739, CM041411; ClinVar: pathogenic; called by muse, varscan2
- PDGFRA | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 72/620 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 150/476 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, varscan2
- PRF1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs28933973, CM992951, COSV64615781; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 90/671 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- RAF1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 199/514 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.069); catalogued as rs587777588, CM145464, COSV52576766; ClinVar: pathogenic; called by muse, varscan2
- RELA | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 35/255 reads (14%) | catalogued as rs1565191003; ClinVar: pathogenic; called by muse, varscan2
- RYR1 | c.14129+1G>A p.X4710_splice | Splice Site (SNP) | VAF 52/127 reads (41%) | catalogued as rs142929172, COSV62110710; ClinVar: pathogenic; called by muse, varscan2
- SCN1A | c.5734C>T p.R1912* (on ENST00000303395 / NM_001202435.3; = p.R1901* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 310/588 reads (53%) | catalogued as rs77216276, CD114895, CM044053, COSV57661348; ClinVar: pathogenic; called by muse, varscan2
- SLC16A1 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 190/527 reads (36%) | catalogued as rs606231300, CM1411338; ClinVar: pathogenic; called by muse, varscan2
- SLC4A11 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 89/204 reads (44%) | catalogued as rs121909390, CM063149; ClinVar: pathogenic; called by muse, varscan2
- SMARCB1 | c.*82C>T | 3'UTR (SNP) | VAF 13/107 reads (12%) | catalogued as rs878854600, CR088415; ClinVar: pathogenic; called by muse, varscan2
- TCF4 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1568303352, CM091864, COSV61890423; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 220/559 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 68/418 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs587781371, CD136796, COSV52684761, COSV53551526; ClinVar: uncertain significance; called by muse, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 21/209 reads (10%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, varscan2
- ZEB2 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 144/365 reads (39%) | catalogued as rs587784566, CM052018, COSV57966620; ClinVar: pathogenic; called by muse, varscan2
- A1BG | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as rs1429367982; called by muse, varscan2
- AACS | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs751887386; called by muse, varscan2
- AAR2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs769313669; called by muse, varscan2
- AASS | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 150/340 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767822862; called by muse, varscan2
- AATK | c.2395G>A p.V799I (on ENST00000326724 / NM_001080395.3; = p.V696I on NM_004920.2) | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs200566125; called by muse, varscan2
- ABCA1 | c.2695G>A p.V899M | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs762040428; called by muse, varscan2
- ABCA2 | c.5095G>A p.D1699N (on ENST00000614293; = p.D1669N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs751895234; called by muse, varscan2
- ABCA5 | c.4901G>A p.R1634Q | Missense Mutation (SNP) | VAF 78/658 reads (12%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as rs374390008; called by muse, varscan2
- ABCA6 | c.4322C>T p.T1441M | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140087185, COSV52642690; called by muse, varscan2
- ABCA7 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs764745232; called by muse, varscan2
- ABCA7 | c.3778G>A p.V1260M | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs760680707, COSV54027797; called by muse, varscan2
- ABCA8 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 140/382 reads (37%) | catalogued as rs368751441; called by muse, varscan2
- ABCB1 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 208/508 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs184290374, COSV55950029; called by muse, varscan2
- ABCB1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 67/637 reads (11%) | catalogued as rs1363838319, COSV55949125, COSV55958612; called by muse, varscan2
- ABCB5 | c.2188C>T p.H730Y (on ENST00000404938 / NM_001163941.2; = p.H285Y on NM_178559.6) | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV99329260; called by muse, varscan2
- ABCB7 | c.1147G>A p.A383T (on ENST00000373394 / NM_001271696.3; = p.A384T on NM_004299.6) | Missense Mutation (SNP) | VAF 200/244 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV99504935; called by muse, varscan2
- ABCB8 | c.1564C>T p.R522C (on ENST00000297504 / NM_001282291.2; = p.R505C on NM_007188.5) | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52507496; called by muse, varscan2
- ABCB8 | c.1709G>A p.R570H (on ENST00000297504 / NM_001282291.2; = p.R553H on NM_007188.5) | Missense Mutation (SNP) | VAF 190/466 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52502519; called by muse, varscan2
- ABCC11 | c.3709G>T p.D1237Y | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765001590; called by muse, varscan2
- ABCC11 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs150250426; called by muse, varscan2
- ABCC12 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs569747930, COSV60918157; called by muse, varscan2
- ABCC4 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 291/765 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs761410807, COSV65311760; called by muse, varscan2
- ABCC5 | c.3830C>T p.P1277L | Missense Mutation (SNP) | VAF 185/535 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765425167; called by muse, varscan2
- ABCG4 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1565817375; called by muse, varscan2
- ABCG8 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 122/348 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs754133516, COSV55391570; called by muse, varscan2
- ABHD11 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 152/406 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as rs147198994, COSV56105232; called by muse, varscan2
- ABHD12 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 210/571 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs774057670; called by muse, varscan2
- ABHD3 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.661); catalogued as COSV104387606, COSV56676021; called by muse, varscan2
- ABI3BP | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 158/447 reads (35%) | catalogued as COSV52543827; called by muse, varscan2
- ABO | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs377147187; called by muse, varscan2
- AC004922.1 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1306120757; called by muse, varscan2
- AC004997.1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 134/329 reads (41%) | SIFT deleterious, low confidence (0); catalogued as rs750588499; called by muse, varscan2
- AC006059.2 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 115/318 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs777005407; called by muse, varscan2
- AC006059.2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 158/466 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs562624230; called by muse, varscan2
- AC008397.2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs140364206; called by muse, varscan2
- AC098582.1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs150158358; called by muse, varscan2
- AC100868.1 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 156/450 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs751310681; called by muse, varscan2
- ACAN | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370626315; called by muse, varscan2
- ACAP2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 134/434 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229683210, COSV100461499, COSV58749569; called by muse, varscan2
- ACE | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs753078890, COSV52017529; called by muse, varscan2
- ACE | c.3537G>A p.W1179* | Nonsense Mutation (SNP) | VAF 146/356 reads (41%) | catalogued as rs1406482731, COSV52003425; called by muse, varscan2
- ACE2 | c.1071G>A p.R357= | Splice Region (SNP) | VAF 28/116 reads (24%) | catalogued as COSV53027291; called by muse, varscan2
- ACHE | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV53819130; called by muse, varscan2
- ACIN1 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs770531376; called by muse, varscan2
- ACLY | c.2620G>A p.G874S | Missense Mutation (SNP) | VAF 41/409 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs1461603121; called by muse, varscan2
- ACLY | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs782383157, COSV61250148; called by muse, varscan2
- ACLY | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 202/496 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs782746157, COSV61251431; called by muse, varscan2
- ACMSD | c.849G>A p.K283= | Splice Region (SNP) | VAF 104/334 reads (31%) | catalogued as rs779358984; called by muse, varscan2
- ACO2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.383); catalogued as rs745579534; ClinVar: uncertain significance; called by muse, varscan2
- ACOT7 | c.1109C>T p.A370V (on ENST00000377855 / NM_181864.3; = p.A360V on NM_007274.4) | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs578211150, COSV100830266; called by muse, varscan2
- ACOX3 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 47/472 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as rs770559924; called by muse, varscan2
- ACP2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as rs1167956730; called by muse, varscan2
- ACSF3 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100441636; called by muse, varscan2
- ACSM5 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141267278; called by muse, varscan2
- ACSS3 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs754483699, COSV99699330; called by muse, varscan2
- ACSS3 | c.1719+1G>T p.X573_splice | Splice Site (SNP) | VAF 158/405 reads (39%) | catalogued as rs1565735489; called by muse, varscan2
- ACTA2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs397516684, CM145697, COSV56515587; ClinVar: uncertain significance; called by muse, varscan2
- ACTL8 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs201038955, COSV64861125; called by muse, varscan2
- ACTL9 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61005154; called by muse, varscan2
- ACTR1A | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 148/376 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV64024335; called by muse, varscan2
- ACTR5 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1291347611, COSV54761243; called by muse, varscan2
- ACTR5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs749402313, COSV99710124; called by muse, varscan2
- ACVR1B | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 169/406 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99231488; called by muse, varscan2
- ACVR2B | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 137/366 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1375880627; called by muse, varscan2
- ADA2 | c.1177G>A p.A393T (on ENST00000262607; = p.A152T on NM_177405.3) | Missense Mutation (SNP) | VAF 126/335 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.402); catalogued as rs746332176, COSV99376464; called by muse, varscan2
- ADAM18 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 276/693 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV99695388, COSV99695854; called by muse, varscan2
- ADAM2 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 84/714 reads (12%) | catalogued as COSV99697247; called by muse, varscan2
- ADAM20 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 54/148 reads (36%) | catalogued as rs1212109496; called by muse, varscan2
- ADAM33 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 170/400 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62936599, COSV62936780; called by muse, varscan2
- ADAMTS14 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs747059045, COSV64600275; called by muse, varscan2
- ADAMTS14 | c.2920C>A p.L974M | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV64604466; called by muse, varscan2
- ADAMTS15 | c.1765G>T p.G589C | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54508023; called by muse, varscan2
- ADAMTS16 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 166/470 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759325136, COSV56999273, COSV99941416; called by muse, varscan2
- ADAMTS17 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.206); catalogued as rs376420999; called by muse, varscan2
- ADAMTS19 | c.1823G>T p.R608I | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.207); catalogued as rs1007394270, COSV50745702; called by muse, varscan2
- ADAMTS2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs546681307, COSV51079230; called by muse, varscan2
- ADAMTS7 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs764208124, COSV101183297; called by muse, varscan2
- ADAMTS7 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147285963; called by muse, varscan2
- ADAMTS7 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 96/379 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs751279737; called by muse, varscan2
- ADAMTSL1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52818812; called by muse, varscan2
- ADAMTSL1 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 188/468 reads (40%) | catalogued as rs761956033, COSV52815302; called by muse, varscan2
- ADAMTSL1 | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs374649653; called by muse, varscan2
- ADARB2 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs139728897; called by muse, varscan2
- ADARB2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV67217398; called by muse, varscan2
- ADAT3 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs773351384; called by muse, varscan2
- ADCK1 | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53080655; called by muse, varscan2
- ADCY2 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.234); catalogued as rs558326351; called by muse, varscan2
- ADCY3 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1465929752; called by muse, varscan2
- ADCY7 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs546408721; called by muse, varscan2
- ADCY7 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs768524618, COSV54269073; called by muse, varscan2
- ADCY8 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53895566; called by muse, varscan2
- ADCYAP1R1 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 182/413 reads (44%) | catalogued as COSV58442582, COSV58444697; called by muse, varscan2
- ADGB | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 264/640 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs1363166411; called by muse, varscan2
- ADGRB1 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1164083455; called by muse, varscan2
- ADGRB1 | c.3592C>T p.R1198C | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1272145393; called by muse, varscan2
- ADGRB2 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 114/328 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748743741; called by muse, varscan2
- ADGRB3 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 215/571 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs780722343; called by muse, varscan2
- ADGRF5 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932322; called by muse, varscan2
- ADGRG3 | c.668-1G>T p.X223_splice | Splice Site (SNP) | VAF 133/348 reads (38%) | catalogued as COSV100341962; called by muse, varscan2
- ADGRL1 | c.3826G>A p.D1276N (on ENST00000340736 / NM_001008701.3; = p.D1271N on NM_014921.5) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs763058520; called by muse, varscan2
- ADGRL3 | c.4411C>T p.P1471S (on ENST00000506720 / NM_001322402.2; = p.P1360S on NM_015236.6) | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.07); catalogued as COSV72230691; called by muse, varscan2
- ADGRV1 | c.2974A>G p.T992A | Missense Mutation (SNP) | VAF 64/488 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs368163419; ClinVar: uncertain significance; called by muse, varscan2
- ADGRV1 | c.4937A>G p.N1646S | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs968118880; called by muse, varscan2
- ADIPOR1 | c.344G>T p.R115I | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579643; called by muse, varscan2
- ADNP2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs201936630; called by muse, varscan2
- ADNP2 | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs372050062; called by muse, varscan2
- ADORA1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99704574; called by muse, varscan2
- ADPRH | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1560069127; called by muse, varscan2
- ADPRHL1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs1318444410; called by muse, varscan2
- ADPRHL1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs912391590; called by muse, varscan2
- ADRA2C | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57468349; called by muse, varscan2
- AF196969.1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 28/141 reads (20%) | PolyPhen possibly damaging (0.653); catalogued as rs377687929; called by muse, varscan2
- AFAP1L2 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 210/530 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751179407; called by muse, varscan2
- AFAP1L2 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 176/458 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754270886, COSV58417808; called by muse, varscan2
- AFDN | c.4205C>T p.A1402V | Missense Mutation (SNP) | VAF 162/406 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as rs1400467163; called by muse, varscan2
- AFF4 | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV54798609; called by muse, varscan2
- AGA | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 124/400 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52805689; called by muse, varscan2
- AGL | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV54049063; called by muse, varscan2
- AGMAT | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs549021034, COSV65436132; called by muse, varscan2
- AGPAT4 | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 49/451 reads (11%) | catalogued as rs767700898; called by muse, varscan2
- AGRN | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1008012998, COSV101039047; called by muse, varscan2
- AGXT | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as CD983927, COSV99048764; called by muse, varscan2
- AHCTF1 | c.5522C>A p.S1841Y (on ENST00000366508; = p.S1815Y on NM_015446.5) | Missense Mutation (SNP) | VAF 154/604 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV100404216; called by muse, varscan2
- AHCTF1 | c.1663C>T p.R555* (on ENST00000366508; = p.R529* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 272/701 reads (39%) | catalogued as COSV58248152; called by muse, varscan2
- AIFM2 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV57160741; called by muse, varscan2
- AIMP2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 200/556 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as rs11544566, COSV52238650, COSV52242016; called by muse, varscan2
- AJM1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs747747733, COSV56032769; called by muse, varscan2
- AKAP6 | c.4048G>A p.A1350T | Missense Mutation (SNP) | VAF 225/536 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs138243272; called by muse, varscan2
- AKAP9 | c.3388C>T p.Q1130* | Nonsense Mutation (SNP) | VAF 198/594 reads (33%) | catalogued as COSV100662071; called by muse, varscan2
- AKAP9 | c.9952C>T p.R3318* (on ENST00000359028; = p.R3294* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 90/742 reads (12%) | catalogued as rs145355395; called by muse, varscan2
- AKAP9 | c.10145G>A p.R3382H (on ENST00000359028; = p.R3358H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/468 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.291); catalogued as rs776193956, COSV62359324; called by muse, varscan2
- AL121899.2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 200/495 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335768228; called by muse, varscan2
- AL121899.2 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV67350454; called by muse, varscan2
- ALAD | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 150/395 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs772042887; called by muse, varscan2
- ALDH1B1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV66619191; called by muse, varscan2
- ALDH1L1 | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV56411252; called by muse, varscan2
- ALDH1L2 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 194/522 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370881324; called by muse, varscan2
- ALG13 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1426287980, COSV52634762; called by muse, varscan2
- ALK | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 164/424 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66566402; called by muse, varscan2
- ALK | c.3251G>A p.R1084H | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs760151617; ClinVar: uncertain significance; called by muse, varscan2
- ALLC | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs866173927; called by muse, varscan2
- ALMS1 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 50/420 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100042993; called by muse, varscan2
- ALMS1 | c.10208C>T p.T3403I | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as rs1231406875; called by muse, varscan2
- ALPI | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761639198; called by muse, varscan2
- ALS2 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); catalogued as rs1559079541; called by muse, varscan2
- ALYREF | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1388519159, COSV100485918; called by muse, varscan2
- AMFR | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 150/362 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs995498781; called by muse, varscan2
- AMFR | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 206/538 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs746312814, COSV99315874; called by muse, varscan2
- AMIGO3 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1357093889; called by muse, varscan2
- AMIGO3 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57537614; called by muse, varscan2
- AMOT | c.2482C>A p.L828M (on ENST00000371959 / NM_001113490.1; = p.L419M on NM_133265.3) | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100494741; called by muse, varscan2
- AMT | c.258+6C>T | Splice Region (SNP) | VAF 72/162 reads (44%) | catalogued as rs1451725049; called by muse, varscan2
- AMZ1 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs780261999; called by muse, varscan2
- ANAPC2 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239291007; called by muse, varscan2
- ANAPC2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs1448409852; called by muse, varscan2
- ANGPT2 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57336066, COSV57337566; called by muse, varscan2
- ANK1 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55894091, COSV99225886; called by muse, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 283/654 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, varscan2
- ANK2 | c.9587C>T p.S3196L | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs144719173, COSV52190287; called by muse, varscan2
- ANKH | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 122/362 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309028634; called by muse, varscan2
- ANKRD1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 190/454 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777320917, COSV63311276; called by muse, varscan2
- ANKRD11 | c.6088G>A p.A2030T | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs747661700; called by muse, varscan2
- ANKRD11 | c.3863C>T p.A1288V | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1269589388; called by muse, varscan2
- ANKRD11 | c.3545G>T p.R1182I | Missense Mutation (SNP) | VAF 184/520 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV56358342; called by muse, varscan2
- ANKRD24 | c.3419G>T p.R1140I | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53671138; called by muse, varscan2
- ANKRD30B | c.3578T>C p.V1193A | Missense Mutation (SNP) | VAF 108/515 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs774022286; called by muse, varscan2
- ANKRD50 | c.3857C>T p.A1286V | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs778120664; called by muse, varscan2
- ANKRD62 | c.1877A>G p.N626S | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1231742611; called by muse, varscan2
- ANKRD63 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.494); catalogued as rs1421456407; called by muse, varscan2
- ANKRD9 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751023237, COSV54601208; called by muse, varscan2
- ANO1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768285449, COSV60288936; called by muse, varscan2
- ANO1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs557778881; called by muse, varscan2
- ANPEP | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs376358699, COSV100263637; called by muse, varscan2
- ANXA9 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV64485574; called by muse, varscan2
- AOX1 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 83/545 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775304628, COSV101022005; called by muse, varscan2
- AP1AR | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 86/246 reads (35%) | catalogued as rs552933023, COSV99914058; called by muse, varscan2
- AP1B1 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 118/432 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs755211454; called by muse, varscan2
- AP1M1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs749149339, COSV52228455; called by muse, varscan2
- AP2B1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 146/436 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1271504512; called by muse, varscan2
- AP3B2 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55610360; called by muse, varscan2
- AP3D1 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as rs754359489; called by muse, varscan2
- AP3M1 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1413291477; called by muse, varscan2
- AP3M2 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 202/525 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs1012403915, COSV104385071; called by muse, varscan2
- AP4E1 | c.2813A>G p.D938G | Missense Mutation (SNP) | VAF 164/488 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs372620158; called by muse, varscan2
- APAF1 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745962333; called by muse, varscan2
- APC | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 156/407 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.265); catalogued as rs147655929; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / benign / likely benign; called by muse, varscan2
- APC | c.4079C>A p.S1360Y | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57367438, COSV99968587; called by muse, varscan2
- APC2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866396845; called by muse, varscan2
- APC2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs144538191; called by muse, varscan2
- APC2 | c.3883C>T p.R1295W | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1409894381; called by muse, varscan2
- APCDD1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1212065765, COSV62371989; called by muse, varscan2
- APTX | c.-111G>T | Splice Region (SNP) | VAF 98/253 reads (39%) | catalogued as COSV58928615; called by muse, varscan2
- AQP4 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 63/540 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs766479946, COSV67218332; called by muse, varscan2
- AQP6 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs1207145859; called by muse, varscan2
- AQR | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs369825498; called by muse, varscan2
- ARAP1 | c.2927G>A p.R976H (on ENST00000393609 / NM_001040118.2; = p.R731H on NM_015242.4) | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1463997107; called by muse, varscan2
- ARF3 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.158); catalogued as rs748329067; called by muse, varscan2
- ARF6 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.954); catalogued as rs61755567; called by muse, varscan2
- ARFGAP1 | c.60C>T p.N20= | Splice Region (SNP) | VAF 124/346 reads (36%) | catalogued as rs1455474493, COSV100796742; called by muse, varscan2
- ARFGEF3 | c.5665G>A p.V1889I | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs773962256, COSV52461651; called by muse, varscan2
- ARHGAP10 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 171/494 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs750229345, COSV60598454; called by muse, varscan2
- ARHGAP20 | c.2527C>T p.R843W | Missense Mutation (SNP) | VAF 200/455 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52820474; called by muse, varscan2
- ARHGAP22 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 190/450 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1479805702; called by muse, varscan2
- ARHGAP32 | c.5476C>T p.R1826C (on ENST00000310343 / NM_001378025.1; = p.R1477C on NM_014715.4) | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs371281246; called by muse, varscan2
- ARHGAP36 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as rs752116998, COSV52264748; called by muse, varscan2
- ARHGAP39 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 172/428 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52770749; called by muse, varscan2
- ARHGAP42 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 203/580 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1049706895, COSV53976118; called by muse, varscan2
- ARHGAP44 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 120/364 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs199982507; called by muse, varscan2
- ARHGAP5 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 172/437 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs764577083; called by muse, varscan2
- ARHGEF10L | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1304379871; called by muse, varscan2
- ARHGEF16 | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV65682891; called by muse, varscan2
- ARHGEF18 | c.1895C>T p.S632L (on ENST00000359920 / NM_001130955.2; = p.S528L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs919074382; called by muse, varscan2
- ARHGEF18 | c.3127C>T p.R1043W (on ENST00000359920 / NM_001130955.2; = p.R939W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs922135452; called by muse, varscan2
- ARHGEF2 | c.1199G>A p.R400H (on ENST00000361247 / NM_001162383.2; = p.R372H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1475947036, COSV58106020; called by muse, varscan2
- ARHGEF25 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866562446; called by muse, varscan2
- ARHGEF33 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 64/643 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1261601937; called by muse, varscan2
- ARHGEF37 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 190/442 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552298903, COSV100381940, COSV61368262; called by muse, varscan2
- ARHGEF39 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs367912783; called by muse, varscan2
- ARHGEF40 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV53883947; called by muse, varscan2
- ARHGEF40 | c.3227G>A p.R1076Q | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs747859875, COSV53878578; called by muse, varscan2
- ARHGEF6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 264/332 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs759340844, COSV51687739; called by muse, varscan2
- ARHGEF7 | c.896G>A p.R299Q (on ENST00000375741 / NM_001113511.2; = p.R121Q on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/669 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.825); catalogued as rs768509936, COSV104374596; called by muse, varscan2
- ARID3B | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.041); catalogued as rs777973099; called by muse, varscan2
- ARID4A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 278/782 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368715644; called by muse, varscan2
- ARID4A | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 184/477 reads (39%) | catalogued as COSV62161933; called by muse, varscan2
- ARMC3 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 206/542 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV99958400; called by muse, varscan2
- ARMC3 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53069637; called by muse, varscan2
- ARMC5 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs747989024, COSV99192306; called by muse, varscan2
- ARMC5 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1048994571, COSV51658463; called by muse, varscan2
- ARMC5 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1477954838, COSV99065168; called by muse, varscan2
- ARRB1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs960206608; called by muse, varscan2
- ARRB2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.937); catalogued as rs1277113932; called by muse, varscan2
- ARSI | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 94/226 reads (42%) | catalogued as COSV60816650; called by muse, varscan2
- ARVCF | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1299818119; called by muse, varscan2
- ASAP2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 106/969 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55639737; called by muse, varscan2
- ASB18 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 180/360 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1454860879; called by muse, varscan2
- ASPHD1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1397977158, COSV100436007; called by muse, varscan2
- ASPM | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 254/594 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034800662, COSV54131872; called by muse, varscan2
- ASS1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs753078725; ClinVar: uncertain significance; called by muse, varscan2
- ASTN1 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs777135736; called by muse, varscan2
- ASTN2 | c.1219G>A p.D407N (on ENST00000313400 / NM_001365069.1; = p.D356N on NM_014010.5) | Missense Mutation (SNP) | VAF 205/548 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.959); catalogued as rs769995748, COSV57815497; called by muse, varscan2
- ASXL3 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 180/419 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52461740; called by muse, varscan2
- ATAD2B | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 204/476 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV53195489; called by muse, varscan2
- ATCAY | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV56654097, COSV56659076; called by muse, varscan2
- ATG2A | c.2980C>T p.R994* | Nonsense Mutation (SNP) | VAF 92/214 reads (43%) | catalogued as rs758190411; called by muse, varscan2
- ATG9A | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 192/460 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs761625801; called by muse, varscan2
- ATP10B | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 42/266 reads (16%) | catalogued as rs201139624, COSV100469476; called by muse, varscan2
- ATP10D | c.3067T>G p.C1023G | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1367324670; called by muse, varscan2
- ATP11A | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs779258751, COSV99370279; called by muse, varscan2
- ATP1A1 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 212/558 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1328025079, COSV55190521; called by muse, varscan2
- ATP1A1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 146/379 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1165006226; called by muse, varscan2
- ATP1B4 | c.670C>T p.R224C (on ENST00000218008 / NM_001142447.3; = p.R220C on NM_012069.5) | Missense Mutation (SNP) | VAF 168/201 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771260677, COSV54314349, COSV54314984; called by muse, varscan2
- ATP1B4 | c.773G>A p.R258H (on ENST00000218008 / NM_001142447.3; = p.R254H on NM_012069.5) | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs143954745, COSV54312118, COSV54315710; called by muse, varscan2
- ATP2A3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 148/336 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs747438391, COSV99989137; called by muse, varscan2
- ATP2B1 | c.1811C>A p.S604Y | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53810754; called by muse, varscan2
- ATP2B2 | c.1490G>A p.R497H (on ENST00000352432; = p.R463H on NM_001683.5) | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs758734872; called by muse, varscan2
- ATP2B3 | c.2744G>A p.G915D | Missense Mutation (SNP) | VAF 114/134 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV54855338; called by muse, varscan2
- ATP2C2 | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 213/553 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750681653, COSV52295192; called by muse, varscan2
- ATP5MC2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 198/519 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs752091763; called by muse, varscan2
- ATP6V0A1 | c.2390C>T p.S797L (on ENST00000343619 / NM_001378531.1; = p.S791L on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/290 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429933097, COSV99230467; called by muse, varscan2
- ATP6V0A4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 228/588 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367645346; called by muse, varscan2
- ATP6V1B2 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 196/506 reads (39%) | catalogued as COSV52354257; called by muse, varscan2
- ATP6V1D | c.307+6G>A | Splice Region (SNP) | VAF 66/439 reads (15%) | catalogued as rs776792817; called by muse, varscan2
- ATP8A2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 66/552 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99684209; called by muse, varscan2
- ATP9A | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs749995941; called by muse, varscan2
- ATR | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 210/606 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV63387244; called by muse, varscan2
- ATRN | c.3470-1G>T p.X1157_splice | Splice Site (SNP) | VAF 80/241 reads (33%) | catalogued as COSV53534700; called by muse, varscan2
- ATRNL1 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs781892443, COSV58075293; called by muse, varscan2
- ATRX | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64885730; called by muse, varscan2
- ATXN1 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as rs756319043; called by muse, varscan2
- ATXN7L1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 154/478 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs751878322; called by muse, varscan2
- ATXN7L2 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 183/483 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV63992993; called by muse, varscan2
- AUTS2 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1005352416; called by muse, varscan2
- AVPR1B | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs1553290605, COSV65638536; called by muse, varscan2
- AXIN1 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs778068596; called by muse, varscan2
- AXIN2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 172/418 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1244431726, COSV100195707; called by muse, varscan2
- B3GALT5 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 64/558 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748085105; called by muse, varscan2
- B3GNT8 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1277091727, COSV99524571, COSV99524889; called by muse, varscan2
- B3GNTL1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 112/434 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs868471231; called by muse, varscan2
- B9D2 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 44/148 reads (30%) | catalogued as rs1286196441; called by muse, varscan2
- BABAM1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100845693, COSV63920164; called by muse, varscan2
- BACH1 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 64/576 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54517243; called by muse, varscan2
- BAG4 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV54861378; called by muse, varscan2
- BAHCC1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555652778; called by muse, varscan2
- BAHCC1 | c.4204G>A p.G1402S | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as rs782149027; called by muse, varscan2
- BAHCC1 | c.7867G>A p.D2623N | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782196785, COSV100312099; called by muse, varscan2
- BAHD1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs143007309; called by muse, varscan2
- BAIAP2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58342365; called by muse, varscan2
- BAIAP2L1 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 188/498 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1003865568; called by muse, varscan2
- BAP1 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 96/265 reads (36%) | catalogued as COSV56239857, COSV56240952; called by muse, varscan2
- BAZ2A | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.019); catalogued as rs775297286, COSV51632740; called by muse, varscan2
- BAZ2B | c.3085C>T p.R1029W | Missense Mutation (SNP) | VAF 128/490 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220985055, COSV54276477; called by muse, varscan2
- BBS2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 262/677 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as rs374487957, COSV55328491; called by muse, varscan2
- BBS4 | c.645C>T p.L215= | Splice Region (SNP) | VAF 214/536 reads (40%) | catalogued as rs373731535; called by muse, varscan2
- BCAN | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs79359814, COSV61256170; called by muse, varscan2
- BCAR3 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs144882670; called by muse, varscan2
- BCL9 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs149196080; called by muse, varscan2
- BCL9L | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs761142257, COSV52686409; called by muse, varscan2
- BCORL1 | c.1818G>T p.Q606H | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV54405541; called by muse, varscan2
- BDP1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 154/402 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1411324817; called by muse, varscan2
- BECN1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 131/366 reads (36%) | catalogued as rs1474337210, COSV100830998; called by muse, varscan2
- BEND7 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 96/395 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs777930278; called by muse, varscan2
- BEST2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs367897325, COSV50370803; called by muse, varscan2
- BICD2 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.8); PolyPhen probably damaging (1); catalogued as rs200091763, COSV63548495; ClinVar: uncertain significance; called by muse, varscan2
- BIRC6 | c.12232G>A p.G4078S | Missense Mutation (SNP) | VAF 65/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101134342; called by muse, varscan2
- BLCAP | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 137/352 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1470854314, COSV50351734; called by muse, varscan2
- BLK | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52049064; called by muse, varscan2
- BLVRB | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs747103556; called by muse, varscan2
- BMP8B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 196/310 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs775172302; called by muse, varscan2
- BMPR2 | c.2467A>G p.T823A | Missense Mutation (SNP) | VAF 174/434 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs778285208; called by muse, varscan2
- BNC1 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs138921537; called by muse, varscan2
- BNIP5 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 161/406 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs770842721; called by muse, varscan2
- BOP1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1017931750; called by muse, varscan2
- BPIFB1 | c.1376C>A p.A459D | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53605193; called by muse, varscan2
- BPIFB4 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs537361835; called by muse, varscan2
- BPNT2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 54/478 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148507660, COSV52907029; called by muse, varscan2
- BPTF | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 127/508 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs759643114, COSV58834684; called by muse, varscan2
- BRD1 | c.3142G>A p.G1048R (on ENST00000216267 / NM_001349940.1; = p.G1179R on NM_001304808.3) | Missense Mutation (SNP) | VAF 196/481 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1489931543, COSV53462298; called by muse, varscan2
- BRD1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs1254272998, COSV99350570; called by muse, varscan2
- BRI3BP | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 117/336 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs145269757; called by muse, varscan2
- BRINP1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs760997991, COSV56310156; called by muse, varscan2
- BRINP1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 143/361 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1453440054, COSV99775127; called by muse, varscan2
- BRINP2 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 139/397 reads (35%) | catalogued as rs138839091, COSV64179456; called by muse, varscan2
- BRINP2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs143438287, COSV100838156; called by muse, varscan2
- BRPF1 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs551623538; called by muse, varscan2
- BRPF3 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 162/398 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761546570, COSV60206960; called by muse, varscan2
- BRSK2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1312075246; called by muse, varscan2
- BRWD1 | c.6559G>T p.V2187L | Missense Mutation (SNP) | VAF 177/524 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as rs1395831791; called by muse, varscan2
- BSN | c.7186C>T p.R2396W | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs774693300; called by muse, varscan2
- BTAF1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 264/676 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs763507976; called by muse, varscan2
- BTAF1 | c.5363G>A p.S1788N | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1291460746, COSV56432469; called by muse, varscan2
- BTBD1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 96/341 reads (28%) | catalogued as rs201223863, COSV99915683; called by muse, varscan2
- BTBD17 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV64730197; called by muse, varscan2
- BTBD3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 98/749 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54777681; called by muse, varscan2
- BTBD7 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs759339337, COSV58285856; called by muse, varscan2
- BTBD8 | c.4874C>A p.S1625Y (on ENST00000636805 / NM_001376131.1; = p.S1112Y on NM_015237.4) | Missense Mutation (SNP) | VAF 75/441 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV64884835; called by muse, varscan2
- BTN3A3 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 228/594 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573665384, COSV55072677; called by muse, varscan2
- BTN3A3 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 146/396 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55071543; called by muse, varscan2
- BUB1 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 249/587 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1360193581; called by muse, varscan2
- C10orf71 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs377136815, COSV60509770; called by muse, varscan2
- C15orf62 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs939466563; called by muse, varscan2
- C16orf46 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1431471450; called by muse, varscan2
- C17orf75 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 84/636 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs563163507; called by muse, varscan2
- C17orf80 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 180/482 reads (37%) | catalogued as rs985141264, COSV52147163; called by muse, varscan2
- C1QB | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 140/378 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs754513747, COSV59245456; called by muse, varscan2
- C1QTNF1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 156/392 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.244); catalogued as rs1171286971; called by muse, varscan2
- C1QTNF2 | c.464C>T p.P155L (on ENST00000393975; = p.P110L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/211 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV101220836; called by muse, varscan2
- C1QTNF2 | c.457C>T p.R153C (on ENST00000393975; = p.R108C on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs554501129, COSV67432492; called by muse, varscan2
- C1QTNF2 | c.404G>A p.R135Q (on ENST00000393975; = p.R90Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as rs368748511; called by muse, varscan2
- C1QTNF5 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1197223354, COSV100264920; ClinVar: uncertain significance; called by muse, varscan2
- C1orf115 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs139711441; called by muse, varscan2
- C1orf122 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 147/372 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs1401063733; called by muse, varscan2
- C22orf15 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs767441367, COSV59418196; called by muse, varscan2
- C4A | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.971); catalogued as rs764710058; called by muse, varscan2
- C5AR1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1391265684, COSV61892510, COSV61893553; called by muse, varscan2
- C5AR2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as rs1479076732, COSV99953730; called by muse, varscan2
- C5orf49 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 149/370 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.371); catalogued as COSV57872965; called by muse, varscan2
- C6orf118 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs368120575, COSV100024854; called by muse, varscan2
- C6orf118 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 121/375 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs757541436, COSV57812526, COSV57812543; called by muse, varscan2
- C7 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 140/410 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as COSV57471099; called by muse, varscan2
- C7orf50 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368280136, COSV62475090; called by muse, varscan2
- C8orf33 | c.551-5G>A | Splice Region (SNP) | VAF 44/430 reads (10%) | catalogued as rs762203508; called by muse, varscan2
- CA11 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs368772133; called by muse, varscan2
- CA11 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.818); catalogued as COSV50032939; called by muse, varscan2
- CABLES2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 136/348 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751037345, COSV99653235; called by muse, varscan2
- CACNA1A | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 54/496 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189054127, COSV64209953; called by muse, varscan2
- CACNA1C | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1183748768; called by muse, varscan2
- CACNA1C | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 191/452 reads (42%) | catalogued as rs1555879031, COSV59704596; called by muse, varscan2
- CACNA1C | c.4624-8G>A | Splice Region (SNP) | VAF 34/226 reads (15%) | catalogued as rs529345041; ClinVar: uncertain significance / likely benign / benign; called by muse, varscan2
- CACNA1E | c.2224A>G p.N742D | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV62424436; called by muse, varscan2
- CACNA1E | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 132/360 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs373647895; called by muse, varscan2
- CACNA1G | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 128/314 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269236876, COSV100661564; called by muse, varscan2
- CACNA1S | c.4415G>A p.R1472H | Missense Mutation (SNP) | VAF 148/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201463541, COSV100754861; called by muse, varscan2
- CACNA1S | c.3697G>A p.A1233T | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs755044361, COSV100754632; called by muse, varscan2
- CACNA2D1 | c.3101C>T p.A1034V (on ENST00000356253 / NM_001366867.1; = p.A1022V on NM_000722.4) | Missense Mutation (SNP) | VAF 159/438 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.299); catalogued as rs747500641, COSV62389667; called by muse, varscan2
- CACNA2D2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781210506, COSV99818083; called by muse, varscan2
- CACNA2D3 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs376945763; called by muse, varscan2
- CACNA2D4 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 44/350 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs769083357, COSV54945729; called by muse, varscan2
- CACNG8 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs1300465014, COSV54413753; called by muse, varscan2
- CACNG8 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99555188; called by muse, varscan2
- CAD | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 164/415 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259923836; called by muse, varscan2
- CAD | c.5516G>A p.R1839H | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773341248, COSV53028743; called by muse, varscan2
- CAD | c.6521G>A p.R2174Q | Missense Mutation (SNP) | VAF 178/483 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as rs750110109, COSV99254657; called by muse, varscan2
- CADM4 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 152/355 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1425865914; called by muse, varscan2
- CALHM2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs141575223; called by muse, varscan2
- CAMK2B | c.1467G>A p.P489= | Splice Region (SNP) | VAF 52/120 reads (43%) | catalogued as rs536589861; called by muse, varscan2
- CAMKK1 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.03); catalogued as rs866002739, COSV99340475; called by muse, varscan2
- CAMSAP1 | c.3962G>A p.R1321H | Missense Mutation (SNP) | VAF 124/283 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100409468, COSV56728851; called by muse, varscan2
- CAMSAP2 | c.3535C>T p.R1179W (on ENST00000236925 / NM_001297707.2; = p.R1168W on NM_203459.3) | Missense Mutation (SNP) | VAF 265/678 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775620824, COSV52666408; called by muse, varscan2
- CAMTA1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 64/441 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs745719073, COSV57885227; called by muse, varscan2
- CAMTA1 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 214/584 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs759300229; called by muse, varscan2
- CAMTA2 | c.2265C>A p.F755L | Missense Mutation (SNP) | VAF 157/408 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61833253; called by muse, varscan2
- CAPG | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 155/391 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs140123804; called by muse, varscan2
- CAPN12 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 39/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs566043949, COSV53147679; called by muse, varscan2
- CAPN5 | c.1520G>A p.R507H (on ENST00000456580; = p.R467H on NM_004055.5) | Missense Mutation (SNP) | VAF 137/336 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs142336480; called by muse, varscan2
- CAPN8 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 61/515 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563351046; called by muse, varscan2
- CAPN8 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1259630222, COSV64814101; called by muse, varscan2
- CARMIL3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 112/277 reads (40%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.885); catalogued as rs763509676; called by muse, varscan2
- CASC3 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 262/678 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs774910900; called by muse, varscan2
- CASKIN1 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | catalogued as COSV58872413; called by muse, varscan2
- CASKIN2 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 162/444 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs140577431; called by muse, varscan2
- CASP6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 188/577 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs547937335; called by muse, varscan2
- CASP8AP2 | c.4703C>T p.S1568F | Missense Mutation (SNP) | VAF 192/500 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV52749947; called by muse, varscan2
- CASZ1 | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs375316064; called by muse, varscan2
- CASZ1 | c.3511G>A p.A1171T | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs769502938, COSV59735301; called by muse, varscan2
- CATSPER4 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 147/562 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as rs777403508; called by muse, varscan2
- CAVIN1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs1283817019, COSV63811330; called by muse, varscan2
- CAVIN4 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.844); catalogued as COSV56868680; called by muse, varscan2
- CBLL1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV56028609; called by muse, varscan2
- CC2D1A | c.2555C>T p.A852V | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as rs907112340, COSV99582900; called by muse, varscan2
- CCDC114 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 178/444 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs751715030, COSV59556314, COSV59558091; called by muse, varscan2
- CCDC137 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775991056; called by muse, varscan2
- CCDC146 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 248/578 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201656358; called by muse, varscan2
- CCDC15 | c.2800C>T p.R934* | Nonsense Mutation (SNP) | VAF 113/350 reads (32%) | catalogued as rs775560747; called by muse, varscan2
- CCDC168 | c.18457C>T p.R6153C | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs574263368, COSV59419810; called by muse, varscan2
- CCDC168 | c.11657C>T p.S3886L | Missense Mutation (SNP) | VAF 178/500 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773465536; called by muse, varscan2
- CCDC168 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 174/461 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70554679, COSV70555770; called by muse, varscan2
- CCDC173 | c.471G>A p.S157= | Splice Region (SNP) | VAF 186/544 reads (34%) | catalogued as rs746348957, COSV69573962; called by muse, varscan2
- CCDC180 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs770803736, COSV63832055; called by muse, varscan2
- CCDC185 | c.1516C>A p.L506M | Missense Mutation (SNP) | VAF 103/234 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV64820575, COSV64821515, COSV64821725; called by muse, varscan2
- CCDC186 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 203/603 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs763015249, COSV65159955; called by muse, varscan2
- CCDC88A | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 114/784 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866318133; called by muse, varscan2
- CCDC88C | c.6023G>A p.S2008N | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100485109; called by muse, varscan2
- CCDC88C | c.5600C>T p.A1867V | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57795817; called by muse, varscan2
- CCDC89 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 202/467 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs777244675, COSV100320857; called by muse, varscan2
- CCDC9 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776376598; called by muse, varscan2
- CCDC97 | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs374299134; called by muse, varscan2
- CCDC9B | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748700372; called by muse, varscan2
- CCIN | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs145849868; called by muse, varscan2
- CCKAR | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 146/358 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV55164736; called by muse, varscan2
- CCNF | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs767126159; called by muse, varscan2
- CCNJL | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs762796829; called by muse, varscan2
- CCNT1 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 190/528 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs777718139; called by muse, varscan2
- CCR1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.586); catalogued as rs181920971; called by muse, varscan2
- CCT3 | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 74/678 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs867370775; called by muse, varscan2
- CCT4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs1218940061; called by muse, varscan2
- CCT5 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 272/699 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs201810364, COSV54723915; called by muse, varscan2
- CCT8 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 261/648 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54503181; called by muse, varscan2
- CD101 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200228819; called by muse, varscan2
- CD109 | c.3157G>A p.V1053I | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as rs952959888; called by muse, varscan2
- CD151 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913313056, COSV58990306; called by muse, varscan2
- CD163L1 | c.3839C>T p.A1280V | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145909473; called by muse, varscan2
- CD40LG | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 120/155 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs104894778, CM930085, COSV65698811; ClinVar: uncertain significance; called by muse, varscan2
- CD84 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as COSV100245783, COSV60868602; called by muse, varscan2
- CDC14C | c.373G>A p.V125M (on ENST00000428251; = p.V18M on NM_152627.3) | Missense Mutation (SNP) | VAF 159/392 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs772953796; called by muse, varscan2
- CDC25B | c.659G>A p.R220H (on ENST00000245960 / NM_021873.3; = p.R206H on NM_004358.4) | Missense Mutation (SNP) | VAF 138/360 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as rs767534464; called by muse, varscan2
- CDC42BPA | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 61/219 reads (28%) | catalogued as rs758392312, COSV62019861; called by muse, varscan2
- CDC42BPB | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 110/341 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1250404274, COSV100775191; called by muse, varscan2
- CDCP2 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs149009344; called by muse, varscan2
- CDH2 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 172/474 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52273654; called by muse, varscan2
- CDH20 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV53005205; called by muse, varscan2
- CDH22 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs200925211; called by muse, varscan2
- CDH3 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 193/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202110644, COSV99868551; called by muse, varscan2
- CDH4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 156/361 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs751765138, COSV64646935; called by muse, varscan2
- CDH4 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1201669774, COSV64648959; called by muse, varscan2
- CDH5 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1182771840; called by muse, varscan2
- CDH7 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.357); catalogued as rs767686297, COSV59883221; called by muse, varscan2
- CDH8 | c.52A>C p.I18L | Missense Mutation (SNP) | VAF 159/390 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100183934; called by muse, varscan2
- CDH9 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 80/634 reads (13%) | catalogued as COSV50407344; called by muse, varscan2
- CDK1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs773501650, COSV57348895; called by muse, varscan2
- CDKAL1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51187004; called by muse, varscan2
- CDRT4 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100381607; called by muse, varscan2
- CDS1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 151/455 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs764952660, COSV55691089; called by muse, varscan2
- CELF6 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 134/318 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs1304948452; called by muse, varscan2
- CELSR1 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs758958784; called by muse, varscan2
- CELSR2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 51/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779467; called by muse, varscan2
- CELSR2 | c.3748G>A p.D1250N | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.787); catalogued as rs781511948; called by muse, varscan2
- CELSR3 | c.9487C>T p.R3163W | Missense Mutation (SNP) | VAF 154/320 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs780807727; called by muse, varscan2
- CENPU | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 162/465 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV55656726, COSV55657111; called by muse, varscan2
- CEP135 | c.3347G>A p.R1116Q | Missense Mutation (SNP) | VAF 156/394 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs191813321; called by muse, varscan2
- CEP152 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 44/445 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57860665; called by muse, varscan2
- CEP170B | c.2261C>T p.S754L (on ENST00000453495; = p.S683L on NM_015005.3) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327590735; called by muse, varscan2
- CEP192 | c.4630C>T p.R1544C | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs761281163; called by muse, varscan2
- CEP250 | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 206/498 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs150723097; called by muse, varscan2
- CEP250 | c.5083C>T p.R1695* | Nonsense Mutation (SNP) | VAF 57/155 reads (37%) | catalogued as rs746831149, COSV61168070; called by muse, varscan2
- CEP290 | c.6125C>T p.S2042F | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs566634807; called by muse, varscan2
- CEP83 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 215/635 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231814558; called by muse, varscan2
- CERS6 | c.404G>T p.S135I | Missense Mutation (SNP) | VAF 217/559 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59828917; called by muse, varscan2
- CETN3 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 258/746 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1343495325, COSV51618119; called by muse, varscan2
- CFAP100 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 56/513 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100729374; called by muse, varscan2
- CFAP251 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 130/368 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.096); catalogued as COSV55839456; called by muse, varscan2
- CFAP251 | c.1874G>A p.S625N | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs1409393761; called by muse, varscan2
- CFAP43 | c.4133G>A p.R1378Q | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240998046, COSV100829083; called by muse, varscan2
- CFAP46 | c.7349C>T p.S2450L | Missense Mutation (SNP) | VAF 147/373 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs750048790; called by muse, varscan2
- CFAP46 | c.4571C>A p.A1524E | Missense Mutation (SNP) | VAF 49/400 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV63952980; called by muse, varscan2
- CFAP46 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770651215, COSV100886526; called by muse, varscan2
- CFAP65 | c.3844C>A p.L1282M | Missense Mutation (SNP) | VAF 122/406 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58558735; called by muse, varscan2
- CFAP74 | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs759416752; called by muse, varscan2
- CFAP92 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | catalogued as rs756051933; called by muse, varscan2
- CFH | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 154/397 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as rs748387954, COSV62777538; called by muse, varscan2
- CFH | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 164/564 reads (29%) | catalogued as rs1354315554, CM1314325, COSV66410123; called by muse, varscan2
- CFTR | c.2294G>A p.R765K | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs557228597, COSV99134051; called by muse, varscan2
- CGN | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 181/467 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769896963; called by muse, varscan2
- CHADL | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1406510605; called by muse, varscan2
- CHD1 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 146/420 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199778938; called by muse, varscan2
- CHD2 | c.3633G>T p.K1211N | Missense Mutation (SNP) | VAF 83/686 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV67707949; called by muse, varscan2
- CHD6 | c.6173C>T p.S2058L | Missense Mutation (SNP) | VAF 155/461 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1386912490; called by muse, varscan2
- CHD7 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 310/715 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.982); catalogued as rs746633621; ClinVar: uncertain significance; called by muse, varscan2
- CHD8 | c.2098C>T p.R700C (on ENST00000646647 / NM_001170629.2; = p.R421C on NM_020920.4) | Missense Mutation (SNP) | VAF 156/436 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868527880, COSV67869986; called by muse, varscan2
- CHM | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 129/158 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs142989054; called by muse, varscan2
- CHRM4 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as rs750280509, COSV59185864; called by muse, varscan2
- CHRM4 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs201003362; called by muse, varscan2
- CHRNA7 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 144/680 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs568931594, COSV60974599; called by muse, varscan2
- CHST1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV57324761, COSV57325892; called by muse, varscan2
- CHST8 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 168/406 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767515326, COSV52861404; called by muse, varscan2
- CIART | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs782348606, COSV51746083; called by muse, varscan2
- CIART | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 154/394 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.319); catalogued as rs782106255; called by muse, varscan2
- CIB3 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 57/474 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs749462543; called by muse, varscan2
- CIDEA | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs146350505; called by muse, varscan2
- CIITA | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs1181384435; called by muse, varscan2
- CILP | c.3254G>A p.R1085H | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs554082158, COSV56024267, COSV56027067; called by muse, varscan2
- CILP2 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs371319583; called by muse, varscan2
- CINP | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 58/530 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs376024315; called by muse, varscan2
- CIRBP | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs775927343; called by muse, varscan2
- CKMT2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 127/346 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs760279735; called by muse, varscan2
- CLASP1 | c.3712C>T p.R1238W | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755382948; called by muse, varscan2
- CLASP1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 106/283 reads (37%) | catalogued as COSV55325822; called by muse, varscan2
- CLCA4 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99760650; called by muse, varscan2
- CLCN1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 172/448 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373130; called by muse, varscan2
- CLCN3 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100641860; called by muse, varscan2
- CLCN4 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250705466; called by muse, varscan2
- CLCN7 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368190250, CM099580; called by muse, varscan2
- CLDN11 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 206/517 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs377105856, COSV50356102; called by muse, varscan2
- CLDN7 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs773251272, COSV100598059; called by muse, varscan2
- CLEC18A | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 50/449 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs753714009; called by muse, varscan2
- CLEC2L | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 209/555 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1176936824, COSV70691093; called by muse, varscan2
- CLEC4M | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs760008267, COSV50216702; called by muse, varscan2
- CLIP1 | c.3360G>T p.Q1120H (on ENST00000620786 / NM_001247997.1; = p.Q1109H on NM_002956.2) | Missense Mutation (SNP) | VAF 138/406 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1481199665; called by muse, varscan2
- CLIP3 | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 66/593 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs778908504; called by muse, varscan2
- CLIP3 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs779187288, COSV100859377; called by muse, varscan2
- CLK4 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 170/466 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs370673005; called by muse, varscan2
- CLN3 | c.1048G>A p.V350I (on ENST00000360019 / NM_001286104.2; = p.V374I on NM_000086.2) | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as rs759049027; ClinVar: uncertain significance; called by muse, varscan2
- CLN8 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 104/278 reads (37%) | catalogued as COSV58670320; called by muse, varscan2
- CLOCK | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 212/620 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761998791; called by muse, varscan2
- CLUAP1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 165/463 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs531380218, COSV58892460; called by muse, varscan2
- CMA1 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 162/398 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV51625995, COSV99157102; called by muse, varscan2
- CMA1 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 66/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs202195650, COSV51625374; called by muse, varscan2
- CMC2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 181/433 reads (42%) | catalogued as rs762821797, COSV54729932; called by muse, varscan2
- CMYA5 | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 180/508 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV71408061; called by muse, varscan2
- CMYA5 | c.6158C>T p.S2053F | Missense Mutation (SNP) | VAF 181/477 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV71408760; called by muse, varscan2
- CNKSR1 | c.1590G>T p.E530D (on ENST00000374253 / NM_001297647.2; = p.E523D on NM_006314.3) | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58794027; called by muse, varscan2
- CNNM4 | c.2130+1G>A p.X710_splice | Splice Site (SNP) | VAF 73/168 reads (43%) | catalogued as rs1403924382; called by muse, varscan2
- CNOT1 | c.4919G>A p.R1640Q | Missense Mutation (SNP) | VAF 162/580 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs181822641, COSV55314781; called by muse, varscan2
- CNOT6 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 129/353 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993647; called by muse, varscan2
- CNOT7 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 58/526 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV61353075; called by muse, varscan2
- CNTNAP3 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1227753900; called by muse, varscan2
- COCH | c.1571G>A p.G524D (on ENST00000216361 / NM_001347720.1; = p.G459D on NM_004086.3) | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs371099832; called by muse, varscan2
- COG2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs752456192, COSV64187152; called by muse, varscan2
- COG6 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 223/584 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs148869108; called by muse, varscan2
- COL18A1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); catalogued as rs557847592, COSV100700662; called by muse, varscan2
- COL19A1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 134/355 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV59582351; called by muse, varscan2
- COL1A1 | c.4248G>A p.T1416= | Splice Region (SNP) | VAF 93/232 reads (40%) | catalogued as rs746565111, COSV56806963; ClinVar: uncertain significance; called by muse, varscan2
- COL21A1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 64/562 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280324762; called by muse, varscan2
- COL22A1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759460539, COSV57339725; called by muse, varscan2
- COL3A1 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 188/465 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.253); catalogued as COSV58581285; called by muse, varscan2
- COL4A1 | c.3716G>T p.G1239V | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011296; called by muse, varscan2
- COL4A1 | c.3331C>T p.P1111S | Missense Mutation (SNP) | VAF 188/482 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs576169751; called by muse, varscan2
- COL4A3 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101170321; called by muse, varscan2
- COL4A5 | c.3400G>T p.G1134C | Missense Mutation (SNP) | VAF 166/211 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302200961; called by muse, varscan2
- COL5A3 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs200094380, COSV53410385; called by muse, varscan2
- COL6A1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs532272312; called by muse, varscan2
- COL6A1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs765826390, COSV62615268; called by muse, varscan2
- COL6A1 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs376807461; called by muse, varscan2
- COL6A2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs373782637; ClinVar: uncertain significance; called by muse, varscan2
- COL6A2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145140058, COSV56002853; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.9070G>A p.V3024I | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs769756403, COSV55100929; called by muse, varscan2
- COL6A5 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758781062, COSV55213950; called by muse, varscan2
- COL6A6 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 178/458 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758140095, COSV100650531, COSV62022061, COSV62023848; called by muse, varscan2
- COL7A1 | c.4485C>T p.G1495= | Splice Region (SNP) | VAF 86/240 reads (36%) | catalogued as rs367958901; called by muse, varscan2
- COL9A2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as rs1215970495; called by muse, varscan2
- COPB2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 260/672 reads (39%) | catalogued as COSV60813222; called by muse, varscan2
- COPG2 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 51/468 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as rs939721137; called by muse, varscan2
- COQ3 | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 152/430 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54640397, COSV54642052; called by muse, varscan2
- CORO1A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54632341; called by muse, varscan2
- CORO2B | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs370083446, COSV55951128; called by muse, varscan2
- COX8A | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs754961342; called by muse, varscan2
- CPA1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782582120, COSV50568256; called by muse, varscan2
- CPNE7 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs532282879, COSV52011005; called by muse, varscan2
- CPO | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 190/592 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs77913277; called by muse, varscan2
- CPS1 | c.1568G>T p.R523I | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV99244075; called by muse, varscan2
- CPS1 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 54/518 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs187479775; called by muse, varscan2
- CPSF1 | c.4166G>A p.R1389H | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs868909999, COSV58234839; called by muse, varscan2
- CPSF1 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.349); catalogued as rs879981428; called by muse, varscan2
- CPT1A | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 158/494 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs751235722, COSV55762003, COSV99680738; called by muse, varscan2
- CPT1B | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs1198187076; called by muse, varscan2
- CPT2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.81); catalogued as COSV99598310; called by muse, varscan2
- CREBBP | c.4996G>A p.A1666T | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as rs1159046430, COSV52143180; called by muse, varscan2
- CREBBP | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1425065110, COSV52132932, COSV52140415, COSV52141766; called by muse, varscan2
- CRELD1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 185/477 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as rs772336477; called by muse, varscan2
- CRK | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 172/442 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs772107356, COSV56032406; called by muse, varscan2
- CROCC | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 120/582 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65013678; called by muse, varscan2
- CROCC | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs776872732, COSV65013238; called by muse, varscan2
- CROCC | c.4912C>T p.R1638W | Missense Mutation (SNP) | VAF 50/449 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs867836490; called by muse, varscan2
- CROCC2 | c.4783C>A p.L1595I | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as rs948323487; called by muse, varscan2
- CRYBG2 | c.4579C>T p.R1527C | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs199611603, COSV57486597; called by muse, varscan2
- CRYBG2 | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs201512016; called by muse, varscan2
- CSAD | c.836G>A p.S279N (on ENST00000444623 / NM_001244705.2; = p.S306N on NM_015989.5) | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs765896871; called by muse, varscan2
- CSAG3 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1195293033; called by muse, varscan2
- CSDE1 | c.520C>T p.R174C (on ENST00000358528 / NM_001007553.3; = p.R143C on NM_007158.6) | Missense Mutation (SNP) | VAF 291/822 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as rs770606954, COSV54739163; called by muse, varscan2
- CSF2RB | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 206/604 reads (34%) | catalogued as rs769513501; called by muse, varscan2
- CSK | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as rs777268682; called by muse, varscan2
- CSMD1 | c.6581C>T p.T2194M (on ENST00000520002; = p.T2193M on NM_033225.6) | Missense Mutation (SNP) | VAF 168/476 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1022424286; called by muse, varscan2
- CSMD2 | c.9558C>T p.V3186= | Splice Region (SNP) | VAF 94/268 reads (35%) | catalogued as COSV53875070; called by muse, varscan2
- CSMD2 | c.8617C>T p.R2873C | Missense Mutation (SNP) | VAF 144/366 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53960112; called by muse, varscan2
- CSNK1A1L | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs748596649, COSV65789483, COSV65790082; called by muse, varscan2
- CSNK1E | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 159/415 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs775283367, COSV63291416; called by muse, varscan2
- CSRNP1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 66/535 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs746438028, COSV99827212; called by muse, varscan2
- CSRNP1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs760808464; called by muse, varscan2
- CST9 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 168/432 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1405418371; called by muse, varscan2
- CTCF | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as COSV50471769; called by muse, varscan2
- CTDP1 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs745430704; called by muse, varscan2
- CTDP1 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs752664929; called by muse, varscan2
- CTIF | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 96/258 reads (37%) | catalogued as rs748876705, COSV56487655; called by muse, varscan2
- CTNNA1 | c.2231G>A p.S744N | Missense Mutation (SNP) | VAF 76/602 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377649610; called by muse, varscan2
- CTNNA2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 199/460 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as COSV63568759; called by muse, varscan2
- CTNNB1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 208/510 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV62696222; called by muse, varscan2
- CTNNB1 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 193/510 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62689922; called by muse, varscan2
- CTNND1 | c.2350G>A p.E784K (on ENST00000399050 / NM_001085458.2; = p.E778K on NM_001331.3) | Missense Mutation (SNP) | VAF 70/640 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768419889; called by muse, varscan2
- CTNND2 | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 132/404 reads (33%) | catalogued as COSV58887770, COSV58902310; called by muse, varscan2
- CTPS1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 210/580 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs1176322200, COSV101009312; called by muse, varscan2
- CTR9 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 208/617 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs781265429; called by muse, varscan2
- CTSC | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 195/573 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs587777534, CM040409, CM993134; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, varscan2
- CTSG | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs112417622; called by muse, varscan2
- CTTNBP2 | c.4763G>A p.S1588N | Missense Mutation (SNP) | VAF 84/691 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770008607; called by muse, varscan2
- CTTNBP2 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 284/734 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs769208688; called by muse, varscan2
- CTXND1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.807); catalogued as rs1431793535; called by muse, varscan2
- CUBN | c.3746G>A p.R1249H | Missense Mutation (SNP) | VAF 80/612 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs151039810; called by muse, varscan2
- CUBN | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs767277942; called by muse, varscan2
- CUL2 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs373408054; called by muse, varscan2
- CUX2 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55623033; called by muse, varscan2
- CWF19L1 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 186/519 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.822); catalogued as rs921211945; called by muse, varscan2
- CXCL17 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.371); catalogued as rs369744406; called by muse, varscan2
- CXCR4 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 98/512 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54014761; called by muse, varscan2
- CYB5RL | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs780876546, COSV55279599, COSV99838827; called by muse, varscan2
- CYFIP2 | c.3265C>T p.R1089W (on ENST00000616178 / NM_001291722.2; = p.R1064W on NM_014376.4) | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1456995793, COSV100556389; called by muse, varscan2
- CYP11A1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 204/504 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51433511; called by muse, varscan2
- CYP11B1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.108); catalogued as COSV52827327; called by muse, varscan2
- CYP1B1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs9341250; called by muse, varscan2
- CYP1B1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs776969875; called by muse, varscan2
- CYP24A1 | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 101/316 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.7); catalogued as rs761110945; called by muse, varscan2
- CYP2D7 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 128/304 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.705); catalogued as rs762414032; called by muse, varscan2
- CYP2W1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as rs369538884; called by muse, varscan2
- CYP4F12 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV61174152; called by muse, varscan2
- CYP4F12 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs199948303, COSV100216079, COSV61173608; called by muse, varscan2
- DAPK1 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774548939; called by muse, varscan2
- DAPK3 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs759587748, COSV100009783; called by muse, varscan2
- DCAF12L1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 123/148 reads (83%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs763268572, COSV64421129, COSV64421800; called by muse, varscan2
- DCAF17 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 164/430 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs1218810468; called by muse, varscan2
- DCAF5 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as rs779993672; called by muse, varscan2
- DCDC1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 120/356 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs746300328; called by muse, varscan2
- DCHS1 | c.5317C>T p.R1773W | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs768625142; called by muse, varscan2
- DCHS1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs764551786, COSV55037496; called by muse, varscan2
- DCLK1 | c.2200C>T p.R734C (on ENST00000360631 / NM_001330072.2; = p.R427C on NM_001195416.2) | Missense Mutation (SNP) | VAF 230/556 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs745824879, COSV55184046; called by muse, varscan2
- DCLK1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs760301962, COSV55184477; called by muse, varscan2
- DCTN1 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs774253609, COSV62621522; called by muse, varscan2
- DDB1 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 154/385 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as rs778871291; called by muse, varscan2
- DDC | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140276979, COSV63565356; called by muse, varscan2
- DDHD1 | c.445C>T p.R149* (on ENST00000323669; = p.R346* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 178/544 reads (33%) | catalogued as rs996382393, COSV60357193; called by muse, varscan2
- DDR2 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV63372598; called by muse, varscan2
- DDX11 | c.2371C>T p.R791W (on ENST00000545668 / NM_152438.2; = p.R741W on NM_004399.3) | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759997809; called by muse, varscan2
- DDX19B | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs772047383, COSV55364136; called by muse, varscan2
- DDX20 | c.1313-1G>T p.X438_splice | Splice Site (SNP) | VAF 44/136 reads (32%) | catalogued as COSV63778286; called by muse, varscan2
- DDX25 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 224/611 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763531991, COSV54993233; called by muse, varscan2
- DDX27 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 180/432 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65628950; called by muse, varscan2
- DDX39A | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99660431; called by muse, varscan2
- DDX46 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 196/528 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62798447; called by muse, varscan2
- DDX56 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 230/638 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs556884834, COSV51835960; called by muse, varscan2
- DDX59 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58752317; called by muse, varscan2
- DDX60 | c.3994G>T p.D1332Y | Missense Mutation (SNP) | VAF 125/330 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67094935; called by muse, varscan2
- DECR2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs141623402, COSV99557296; called by muse, varscan2
- DEF6 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.825); catalogued as rs768317306; called by muse, varscan2
- DEF8 | c.427G>A p.V143I (on ENST00000268676 / NM_207514.3; = p.V82I on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/407 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230200388; called by muse, varscan2
- DEGS2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs367704730; called by muse, varscan2
- DENND1A | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs554854472, COSV101011339; called by muse, varscan2
- DENND2A | c.2428G>A p.V810M | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1203911611; called by muse, varscan2
- DENND2A | c.2327+7G>A | Splice Region (SNP) | VAF 158/427 reads (37%) | catalogued as rs773384220; called by muse, varscan2
- DEPDC5 | c.2768G>A p.R923H (on ENST00000400246; = p.R992H on NM_014662.5) | Missense Mutation (SNP) | VAF 56/478 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1473617562; called by muse, varscan2
- DEPTOR | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 150/420 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs1018353484; called by muse, varscan2
- DGKD | c.2868G>T p.Q956H (on ENST00000264057 / NM_152879.3; = p.Q912H on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs762456301; called by muse, varscan2
- DGKE | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 71/456 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52350272; called by muse, varscan2
- DHCR7 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1253213550, COSV62795237; called by muse, varscan2
- DHRS11 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs754322863; called by muse, varscan2
- DHRSX | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs372205535, COSV100585985; called by muse, varscan2
- DHX15 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs772864640; called by muse, varscan2
- DHX29 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 72/522 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1231615237; called by muse, varscan2
- DHX33 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as rs375120834; called by muse, varscan2
- DHX38 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 74/203 reads (36%) | catalogued as rs1385706449, COSV51696590; called by muse, varscan2
- DICER1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 234/570 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.156); catalogued as rs745802492, COSV100602263; ClinVar: uncertain significance; called by muse, varscan2
- DIDO1 | c.5855C>T p.A1952V | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.308); catalogued as rs753664129, COSV56623750; called by muse, varscan2
- DIDO1 | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs142581504; called by muse, varscan2
- DIP2A | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1047774685, COSV59471091; called by muse, varscan2
- DIP2A | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as rs759551999; called by muse, varscan2
- DIP2A | c.4402C>T p.R1468W | Missense Mutation (SNP) | VAF 158/455 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750831684, COSV59475667; called by muse, varscan2
- DIPK2B | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 66/76 reads (87%) | catalogued as rs1409201573; called by muse, varscan2
- DIS3L | c.785G>A p.R262Q (on ENST00000319212 / NM_001143688.3; = p.R179Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs372960179; called by muse, varscan2
- DIS3L | c.1449A>C p.E483D (on ENST00000319212 / NM_001143688.3; = p.E400D on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1448960814; called by muse, varscan2
- DISP3 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as rs767319504; called by muse, varscan2
- DISP3 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.033); catalogued as rs778797542, COSV53826308; called by muse, varscan2
- DLC1 | c.3500C>T p.S1167L (on ENST00000276297 / NM_001348081.2; = p.S730L on NM_006094.5) | Missense Mutation (SNP) | VAF 194/544 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1386825345; called by muse, varscan2
- DLC1 | c.3298C>T p.R1100* (on ENST00000276297 / NM_001348081.2; = p.R663* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 69/442 reads (16%) | catalogued as rs763428774, COSV52331440; called by muse, varscan2
- DLG3 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 132/167 reads (79%) | SIFT tolerated (0.54); PolyPhen benign (0.311); catalogued as rs748814438, COSV52084936; called by muse, varscan2
- DLG4 | c.1660G>A p.E554K (on ENST00000399506 / NM_001321075.3; = p.E597K on NM_001365.4) | Missense Mutation (SNP) | VAF 188/402 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs775416014, COSV57239742; called by muse, varscan2
- DLG4 | c.398C>T p.A133V (on ENST00000399506 / NM_001321075.3; = p.A176V on NM_001365.4) | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs982251458; called by muse, varscan2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, varscan2
- DLGAP1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV59800338; called by muse, varscan2
- DLGAP2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.975); catalogued as rs1278208729; called by muse, varscan2
- DLGAP4 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs1191466666, COSV100211022; called by muse, varscan2
8,977 further variants in this file (5,241 protein-altering or splice-affecting, 2,113 silent, 1,623 other) are not listed here.
